Somatic mutation profile of tumor specimen TCGA-D7-5577-01A (aliquot TCGA-D7-5577-01A-01D-1600-08) from TCGA case TCGA-D7-5577, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 53.8 years (19,668 days).
Specimen TCGA-D7-5577-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 997b5576-f9e3-4190-ba98-909d53cb7030.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-5577-10A (Blood Derived Normal), aliquot TCGA-D7-5577-10A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5811d4fb-22a7-49b7-b147-8702fde2f02b

The open-access MAF lists 123 somatic variants for this specimen: 97 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 23, Nonsense Mutation 7, Frame Shift Del 3, Intron 2, 5'Flank 1, Splice Site 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 79/219 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1057519733, CM083720, COSV61068654; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 79/237 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3129G>T p.M1043I | Missense Mutation (SNP) | VAF 92/142 reads (65%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs121913283, CM126698, COSV55873376, COSV55878974, COSV55898229; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.377C>A p.A126D | Missense Mutation (SNP) | VAF 83/165 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64290343, COSV64290444, COSV64294220; called by muse, mutect2, varscan2
- ABCA3 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 93/246 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs370347086; called by muse, mutect2, varscan2
- ADCY10 | c.3121G>A p.V1041I | Missense Mutation (SNP) | VAF 72/238 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs202210889, COSV63240802; called by muse, mutect2, varscan2
- AGA | c.546C>A p.Y182* | Nonsense Mutation (SNP) | VAF 35/122 reads (29%) | catalogued as COSV52806258; called by muse, mutect2, varscan2
- APLNR | c.1104A>T p.K368N | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.351); catalogued as rs1213912764, COSV57242559; called by muse, mutect2, varscan2
- ARID1A | c.4336C>T p.R1446* | Nonsense Mutation (SNP) | VAF 40/139 reads (29%) | catalogued as COSV61370903, COSV61383151; called by muse, mutect2, varscan2
- ATP8A1 | c.3433G>A p.V1145I | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.142); catalogued as rs779394605, COSV52534956; called by muse, mutect2, varscan2
- ATP8B4 | c.3518T>A p.L1173* | Nonsense Mutation (SNP) | VAF 128/388 reads (33%) | catalogued as COSV52715251; called by muse, mutect2, varscan2
- BAG5 | c.275T>C p.I92T | Missense Mutation (SNP) | VAF 95/307 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs187928827, COSV54571055; called by muse, mutect2, varscan2
- BCORL1 | c.4814T>G p.L1605R | Missense Mutation (SNP) | VAF 79/235 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54396088; called by muse, mutect2, varscan2
- BLK | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs140188373; called by muse, mutect2, varscan2
- BUB1B | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55012452; called by muse, mutect2, varscan2
- C11orf94 | c.131C>A p.S44Y | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV53797769, COSV99571863; called by muse, mutect2, varscan2
- CA6 | c.211T>A p.Y71N | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66262150; called by muse, mutect2, varscan2
- CDRT1 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV55411667; called by muse, mutect2
- CEP85L | c.382A>C p.S128R | Missense Mutation (SNP) | VAF 62/209 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.414); catalogued as COSV63823085; called by muse, mutect2, varscan2
- CRACDL | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV67408064, COSV67409577; called by muse, mutect2, varscan2
- CSMD1 | c.9343C>T p.R3115C (on ENST00000520002; = p.R3114C on NM_033225.6) | Missense Mutation (SNP) | VAF 76/231 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); catalogued as rs746788756, COSV59322529; called by muse, mutect2, varscan2
- CTNND2 | c.1910G>T p.G637V | Missense Mutation (SNP) | VAF 85/337 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58888167; called by muse, mutect2, varscan2
- DNTTIP1 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.934); catalogued as COSV65459817; called by muse, mutect2, varscan2
- F8 | c.6833A>C p.E2278A | Missense Mutation (SNP) | VAF 98/334 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV57705137, COSV57705150; called by muse, varscan2
- FRRS1 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV54922037; called by muse, mutect2, varscan2
- GABRG2 | c.262A>C p.K88Q | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV62717962; called by muse, mutect2, varscan2
- GTF2E1 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV52204261; called by muse, mutect2, varscan2
- GTPBP3 | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50177011; called by muse, mutect2, varscan2
- HOXB9 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762781006, COSV60817089; called by muse, mutect2, varscan2
- HSP90AB1 | c.1532T>C p.V511A | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV62334497; called by muse, mutect2, varscan2
- ICE1 | c.4069G>T p.D1357Y | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as COSV56821548, COSV56824531; called by muse, mutect2, varscan2
- ITIH6 | c.178T>A p.F60I | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV54489046; called by muse, mutect2, varscan2
- ITK | c.950C>G p.P317R | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68435333; called by muse, mutect2, varscan2
- ITPR2 | c.1480C>A p.L494M | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67269204; called by muse, mutect2, varscan2
- KIR3DL1 | c.352A>C p.T118P | Missense Mutation (SNP) | VAF 162/319 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV58490633; called by muse, mutect2, varscan2
- KLHL1 | c.2222G>A p.C741Y | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV64772234; called by muse, mutect2, varscan2
- LHFPL3 | c.618G>T p.E206D | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.37); PolyPhen benign (0.037); catalogued as COSV67811195; called by muse, mutect2, varscan2
- MAN1C1 | c.1378G>A p.A460T | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as rs753090086, COSV56044562; called by muse, mutect2, varscan2
- MAN2B2 | c.1519G>A p.G507S | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763353568, COSV53452924; called by muse, mutect2, varscan2
- MIB1 | c.1405C>T p.Q469* | Nonsense Mutation (SNP) | VAF 33/93 reads (35%) | catalogued as COSV55090403; called by muse, mutect2, varscan2
- MME | c.1541A>T p.N514I | Missense Mutation (SNP) | VAF 73/108 reads (68%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.91); catalogued as COSV64707387, COSV64710978; called by muse, mutect2, varscan2
- MPP6 | c.168C>G p.N56K | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV56038134; called by muse, mutect2, varscan2
- MRC2 | c.4238C>T p.A1413V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775059158, COSV57639655; called by muse, mutect2, varscan2
- MTMR3 | c.2678C>T p.P893L | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV60304257; called by muse, mutect2, varscan2
- MUC20 | c.1646C>A p.A549E | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV57849638; called by muse, mutect2, varscan2
- MUC5B | c.16571C>T p.S5524L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs756336123, COSV71592021; called by muse, mutect2, varscan2
- MYH1 | c.5533C>T p.R1845C | Missense Mutation (SNP) | VAF 64/259 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1039075314, COSV56843263; called by muse, mutect2, varscan2
- NAV1 | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV55217513; called by muse, mutect2, varscan2
- NBEA | c.6638G>A p.R2213Q | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as COSV59783155; called by muse, mutect2, varscan2
- NCR2 | c.344C>A p.S115Y | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66100566; called by muse, mutect2, varscan2
- NLGN4X | c.2330A>T p.N777I | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); catalogued as COSV52017339; called by muse, mutect2, varscan2
- NOS1 | c.3469G>A p.E1157K | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV57612189; called by muse, mutect2, varscan2
- NOS2 | c.1295C>T p.T432I | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV58223715; called by muse, mutect2, varscan2
- NR4A3 | c.155C>A p.T52N | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV58244901; called by muse, mutect2, varscan2
- PALMD | c.281A>C p.K94T | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.911); catalogued as COSV54164426, COSV54164486; called by muse, mutect2, varscan2
- PCDH11X | c.1546G>T p.D516Y | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53439062, COSV53464765; called by muse, mutect2, varscan2
- PCDHA2 | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV65366943, COSV65372235; called by muse, mutect2, varscan2
- PEG3 | c.242C>T p.T81I | Missense Mutation (SNP) | VAF 172/300 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV55629524, COSV55633236; called by muse, mutect2, varscan2
- PIDD1 | c.2308G>C p.A770P | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs751826900, COSV57193258; called by muse, mutect2, varscan2
- PNPLA3 | c.1058A>G p.Y353C | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53378243; called by muse, mutect2, varscan2
- POTEF | c.2465T>G p.I822S | Missense Mutation (SNP) | VAF 96/260 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV62541236; called by muse, varscan2
- PPRC1 | c.4942T>C p.S1648P | Missense Mutation (SNP) | VAF 99/329 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV53385324; called by muse, mutect2, varscan2
- PRCC | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 59/205 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.854); catalogued as rs139572885; called by muse, mutect2, varscan2
- PREX2 | c.3814G>T p.V1272L | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as COSV55769235; called by muse, mutect2, varscan2
- PRPF6 | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.654); catalogued as COSV53870458; called by muse, mutect2, varscan2
- PRPF8 | c.3082T>A p.Y1028N | Missense Mutation (SNP) | VAF 85/319 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV59263405; called by muse, mutect2, varscan2
- PTPRM | c.1551+1G>T p.X517_splice | Splice Site (SNP) | VAF 19/95 reads (20%) | catalogued as COSV59858242; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2797C>A p.P933T | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs777581558, COSV51482092; called by muse, mutect2, varscan2
- RNF217 | c.1322G>T p.C441F (on ENST00000521654 / NM_001286398.2; = p.C149F on NM_152553.5) | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51575791; called by muse, mutect2, varscan2
- SIRPA | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs369093228; called by muse, mutect2, varscan2
- SKIL | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 113/186 reads (61%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV52059783; called by muse, mutect2, varscan2
- STAM | c.484A>C p.K162Q | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV66325357; called by muse, mutect2, varscan2
- STYXL2 | c.908G>A p.S303N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54805022; called by muse, varscan2
- SYNPO2 | c.3358G>A p.D1120N | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs1308307269, COSV61110699; called by muse, mutect2, varscan2
- TACC1 | c.2299C>T p.R767C | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149836912; called by muse, mutect2, varscan2
- TIPARP | c.140G>A p.R47K | Missense Mutation (SNP) | VAF 79/223 reads (35%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.005); catalogued as COSV55814061; called by muse, mutect2, varscan2
- TMEM171 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 164/537 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs777521225, COSV55130313; called by muse, mutect2, varscan2
- TRPS1 | c.997T>G p.F333V (on ENST00000220888 / NM_001330599.2; = p.F346V on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV55239820; called by muse, mutect2, varscan2
- TTN | c.31157A>C p.K10386T (on ENST00000591111; = p.K9459T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/102 reads (37%) | PolyPhen probably damaging (0.994); catalogued as COSV60052796; called by muse, mutect2, varscan2
- TTN | c.19687G>A p.A6563T (on ENST00000591111; = p.A5636T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/110 reads (30%) | PolyPhen benign (0.001); catalogued as rs753356990, COSV59873924, COSV59891082; ClinVar: not provided; called by muse, mutect2, varscan2
- VPS13A | c.5158G>A p.E1720K | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs1564724229, COSV62429644; called by muse, mutect2, varscan2
- VSIG4 | c.1166A>C p.E389A | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV66073707; called by muse, mutect2, varscan2
- ZBTB26 | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.358); catalogued as COSV101021024, COSV65403188; called by muse, mutect2, varscan2
- ZFP28 | c.390G>C p.K130N | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV56735796; called by muse, mutect2, varscan2
- ZMYND8 | c.3186C>A p.C1062* (on ENST00000311275 / NM_001363741.2; = p.C1036* on NM_012408.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 48/186 reads (26%) | catalogued as COSV53687475; called by muse, mutect2, varscan2
- ZNF292 | c.7658C>T p.A2553V | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV60539327; called by muse, mutect2, varscan2
- ZNF324 | c.804G>C p.K268N | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.212); catalogued as COSV99543305; called by muse, mutect2, varscan2
- ZNF660 | c.816A>C p.K272N | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59549022; called by muse, mutect2
- ZSWIM8 | c.3146C>T p.A1049V (on ENST00000605216 / NM_001242487.2; = p.A1054V on NM_015037.3) | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV67132472; called by muse, mutect2, varscan2
- ASB15 | c.1684A>T p.K562* | Nonsense Mutation (SNP) | VAF 28/157 reads (18%) | called by muse, varscan2
- ASB15 | c.1696_1705del p.P566Ffs*17 | Frame Shift Del (DEL) | VAF 20/136 reads (15%) | called by pindel, varscan2
- IGLV3-25 | c.98C>A p.P33Q | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, varscan2
- LIPI | c.1245del p.F415Lfs*2 | Frame Shift Del (DEL) | VAF 38/185 reads (21%) | called by mutect2, pindel, varscan2
- MYO1E | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- OR4N2 | c.917_919delinsAA p.I306Kfs*? (on ENST00000315947; = p.I306Kfs*16 on NM_001004723.3) | Frame Shift Del (DEL) | VAF 12/95 reads (13%) | called by pindel, varscan2*
- PRRG3 | c.275dup p.I93Dfs*49 | Frame Shift Ins (INS) | VAF 127/446 reads (28%) | called by mutect2, pindel, varscan2
- TNFRSF13C | c.442_444del p.P148del | In Frame Del (DEL) | VAF 15/76 reads (20%) | called by pindel, varscan2
- ANKRD27 | c.2820C>T p.Y940= | Silent (SNP) | VAF 24/140 reads (17%) | catalogued as rs754949637, COSV60131493; called by muse, mutect2, varscan2
- BPNT2 | c.219C>T p.A73= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV52907419; called by muse, mutect2
- C8orf58 | c.663C>T p.P221= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs772940202, COSV51515194; called by muse, mutect2, varscan2
- CD22 | c.252G>A p.K84= | Silent (SNP) | VAF 22/193 reads (11%) | catalogued as COSV50052620; called by muse, mutect2, varscan2
- CDH12 | c.1767C>A p.V589= | Silent (SNP) | VAF 44/194 reads (23%) | catalogued as COSV66404726; called by muse, mutect2, varscan2
- CNTNAP5 | c.2859G>A p.R953= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs1308693597, COSV70485593; called by muse, mutect2, varscan2
- CTSD | c.816C>T p.V272= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV52588213; called by muse, mutect2, varscan2
- HSPG2 | c.6912C>T p.A2304= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs755251798, COSV65971495; called by muse, mutect2
- MAT2A | c.1182A>G p.K394= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV52088275; called by muse, varscan2
- MDN1 | c.3489G>A p.A1163= | Silent (SNP) | VAF 55/277 reads (20%) | catalogued as rs764850569, COSV65521476; called by muse, mutect2, varscan2
- MEX3B | c.1224C>T p.S408= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs766495716, COSV61663418; called by muse, mutect2, varscan2
- MSX1 | c.546G>A p.A182= | Silent (SNP) | VAF 48/163 reads (29%) | catalogued as rs140353960; called by muse, mutect2, varscan2
- NALCN | c.3211T>C p.L1071= | Silent (SNP) | VAF 60/166 reads (36%) | catalogued as rs1050752338, COSV51935059; called by muse, mutect2, varscan2
- NNT | c.2133T>G p.G711= | Silent (SNP) | VAF 35/132 reads (27%) | catalogued as rs373432420; called by muse, mutect2, varscan2
- PCDHA4 | c.1449C>T p.D483= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as COSV63540896, COSV63543934; called by muse, mutect2, varscan2
- PDP1 | c.780C>T p.L260= | Silent (SNP) | VAF 61/203 reads (30%) | catalogued as rs140224111; called by muse, mutect2, varscan2
- PEG3 | c.984G>A p.S328= | Silent (SNP) | VAF 56/246 reads (23%) | catalogued as rs766518038, COSV55628121; called by muse, varscan2
- POLI | c.1185G>A p.Q395= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV54189136; called by muse, mutect2, varscan2
- SLC35F3 | c.339G>A p.P113= (on ENST00000366617 / NM_001300845.1; = p.P182= on NM_173508.4) | Silent (SNP) | VAF 17/288 reads (6%) | catalogued as rs374911955; called by muse, mutect2
- TBX15 | c.1089T>C p.S363= (on ENST00000369429 / NM_001330677.2; = p.S257= on NM_152380.3) | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV52871092; called by muse, mutect2, varscan2
- TSNAX | c.324A>T p.L108= | Silent (SNP) | VAF 80/246 reads (33%) | catalogued as COSV64146296; called by muse, mutect2, varscan2
- WWC3 | c.1893G>A p.A631= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs184706668, COSV66503253; called by muse, mutect2
- ZHX3 | c.1536C>T p.S512= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as COSV58383431; called by muse, mutect2, varscan2
- ARHGAP6 | c.589-35704T>G | Intron (SNP) | VAF 58/188 reads (31%) | catalogued as COSV100498155; called by muse, mutect2, varscan2
- DCAF13 | chr8:103415380 G>A | 5'Flank (SNP) | VAF 6/74 reads (8%) | catalogued as COSV52567671; called by muse, mutect2
- MACF1 | c.15832-11923G>A | Intron (SNP) | VAF 40/138 reads (29%) | catalogued as COSV57120705; called by muse, mutect2, varscan2
